Somatic mutation profile of tumor specimen TCGA-GS-A9U3-01A (aliquot TCGA-GS-A9U3-01A-11D-A38X-10) from TCGA case TCGA-GS-A9U3, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 78.0 years (28,474 days).
Specimen TCGA-GS-A9U3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d78eecef-a969-4295-a3ae-ab0cbb78fd32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9U3-10A (Blood Derived Normal), aliquot TCGA-GS-A9U3-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d6030a6-8dd4-441d-a731-da09cfdf1922

The open-access MAF lists 85 somatic variants for this specimen: 64 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 18, Nonsense Mutation 6, Intron 2, 3'UTR 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.1463T>A p.I488N (on ENST00000326195 / NM_001025091.2; = p.I450N on NM_001090.3) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100400862; called by muse, mutect2, varscan2
- AGA | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226362869, COSV99219537; called by muse, mutect2
- ANKRD50 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs755391724, COSV101538964; called by muse, mutect2, varscan2
- AP002748.5 | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.741); catalogued as rs758544060, COSV100567962; called by muse, mutect2, varscan2
- BCL10 | c.645T>A p.C215* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100997803; called by muse, mutect2, varscan2
- C1QTNF2 | c.310C>T p.R104* (on ENST00000393975; = p.R59* on NM_031908.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as rs144600396; called by muse, mutect2, varscan2
- CARD17 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100995230; called by mutect2, varscan2
- CDC25B | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99847930; called by muse, mutect2, varscan2
- CELSR1 | c.3697G>A p.A1233T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs200980049; called by muse, mutect2, varscan2
- CEP104 | c.2576G>A p.W859* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100986626; called by muse, mutect2, varscan2
- CEP85 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs753729078, COSV99432396; called by muse, mutect2, varscan2
- CHM | c.1900G>T p.A634S | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV100753345; called by muse, mutect2
- COL9A1 | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294852; called by muse, mutect2, varscan2
- CSNK1A1L | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.578); catalogued as rs558439842, COSV65790358; called by muse, mutect2, varscan2
- DLG2 | c.2006A>T p.Y669F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99716341; called by muse, mutect2
- DNAH7 | c.10777C>T p.R3593W | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200008102, COSV100415379; called by muse, mutect2, varscan2
- DOCK5 | c.3541C>T p.R1181W | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs780213767, COSV52416302; called by muse, mutect2, varscan2
- EPHA6 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1374125907, COSV101063111, COSV67585991; called by muse, mutect2, varscan2
- EPPK1 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs544383532, COSV101599854; called by muse, mutect2, varscan2
- ERICH3 | c.2795A>G p.E932G | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV100444500; called by muse, mutect2, varscan2
- FAM117A | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as rs779032156, COSV99544851; called by muse, mutect2, varscan2
- FZD10 | c.1537G>C p.V513L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.268); catalogued as COSV99969450; called by muse, mutect2, varscan2
- GABRG3 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100407475; called by muse, mutect2, varscan2
- GPR50 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.344); catalogued as COSV99506190; called by muse, mutect2, varscan2
- H1-5 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs771262830, COSV100137908; called by muse, mutect2, varscan2
- IGHV4-34 | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as rs587731199; called by muse, varscan2
- INO80 | c.3908A>G p.K1303R | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV100731840; called by muse, mutect2, varscan2
- INO80 | c.3529C>T p.R1177* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100731843; called by muse, mutect2
- KRTAP11-1 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100190654; called by muse, mutect2, varscan2
- LIMD1 | c.8A>T p.K3M | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99836972; called by muse, mutect2, varscan2
- LY9 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs374075565; called by muse, mutect2, varscan2
- MID2 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV99464777; called by muse, mutect2, varscan2
- MRPL19 | c.458A>T p.N153I | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100718802; called by muse, mutect2, varscan2
- MST1R | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs367549694; called by muse, mutect2, varscan2
- OR52L1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.894); catalogued as COSV100176181; called by muse, mutect2, varscan2
- P4HA3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100525745; called by muse, mutect2, varscan2
- PAM | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99173550; called by muse, mutect2
- PCDHA10 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV56552425; called by muse, mutect2, varscan2
- PCDHA2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs781896269, COSV65367560; called by muse, mutect2, varscan2
- PCNX3 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs770482265, COSV100856425; called by muse, mutect2, varscan2
- PIP5K1A | c.680A>G p.Y227C (on ENST00000368888 / NM_001135638.2; = p.Y214C on NM_003557.3) | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100576630; called by muse, mutect2, varscan2
- PLCL2 | c.667G>A p.G223R (on ENST00000615277 / NM_001144382.2; = p.G97R on NM_015184.5) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs780485591, COSV101196757; called by muse, mutect2
- PLEKHH2 | c.262T>C p.C88R | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as rs774892086, COSV99174793; called by muse, mutect2, varscan2
- PPP4C | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV54222859; called by muse, mutect2, varscan2
- PXDNL | c.4113A>T p.E1371D | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100683947; called by muse, mutect2, varscan2
- QSOX2 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs747175246, COSV100699772; called by muse, varscan2
- ROBO1 | c.3932A>C p.Y1311S | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs144314391, COSV101458774; called by muse, varscan2
- RSBN1L | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV100616066; called by muse, mutect2, varscan2
- SHANK1 | c.6176C>T p.P2059L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs571797572, COSV99521321; called by muse, mutect2, varscan2
- SHISAL1 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as rs372785890; called by muse, mutect2, varscan2
- SLC16A12 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV100370233; called by muse, mutect2, varscan2
- SPOCD1 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as rs1252871930, COSV99929948; called by muse, mutect2, varscan2
- SSTR2 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs1478324784, COSV100192083; called by muse, mutect2, varscan2
- TJP2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs1339462786, COSV99601187; called by muse, mutect2, varscan2
- TLL2 | c.1079del p.G360Efs*32 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | catalogued as rs753509952, COSV63571285; called by mutect2, pindel, varscan2
- TNS1 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as rs751419226, COSV50701348, COSV99410028; called by muse, mutect2, varscan2
- UBQLN2 | c.136T>A p.F46I | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.213); catalogued as COSV100592727, COSV57739251; called by muse, mutect2, varscan2
- USP9X | c.5398T>G p.F1800V | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100199349; called by muse, mutect2, varscan2
- VMA21 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57756912; called by muse, mutect2, varscan2
- ZC4H2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs752785512, COSV62006317; called by muse, mutect2, varscan2
- ZFHX4 | c.8593C>A p.L2865I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.113); catalogued as rs754279484, COSV50695273; called by muse, mutect2, varscan2
- IGLL5 | c.448dup p.W150Lfs*51 | Frame Shift Ins (INS) | VAF 24/162 reads (15%) | called by mutect2, pindel, varscan2
- MAP1A | c.4998G>T p.E1666D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2
- ZNF395 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2
- ADAMTS19 | c.1116G>C p.L372= | Silent (SNP) | VAF 18/396 reads (5%) | called by muse, mutect2
- AHRR | c.765G>A p.P255= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs371473301; called by muse, mutect2, varscan2
- CNNM2 | c.1548A>G p.K516= | Silent (SNP) | VAF 9/164 reads (5%) | catalogued as COSV100881727; called by muse, mutect2
- IGKJ5 | c.9C>G p.T3= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs375348000; called by muse, varscan2
- IGKV4-1 | c.300C>T p.T100= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs757289290; called by muse, mutect2
- INCENP | c.894G>A p.T298= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs760253258, COSV53916832; called by muse, mutect2, varscan2
- NMBR | c.435C>A p.I145= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV99237284; called by muse, mutect2, varscan2
- OR4A15 | c.510T>C p.N170= | Silent (SNP) | VAF 47/278 reads (17%) | catalogued as COSV100124120; called by muse, mutect2, varscan2
- PAPPA | c.3402C>T p.L1134= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100074255; called by muse, mutect2, varscan2
- PCDHB1 | c.483C>T p.D161= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100128186; called by muse, mutect2, varscan2
- POF1B | c.744C>A p.G248= | Silent (SNP) | VAF 54/335 reads (16%) | catalogued as COSV99426766; called by muse, mutect2, varscan2
- POGK | c.666G>A p.K222= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV100902490; called by muse, mutect2
- RBMXL2 | c.813G>A p.G271= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs138708788, COSV100182223; called by muse, mutect2, varscan2
- ROBO1 | c.3144T>C p.N1048= | Silent (SNP) | VAF 9/280 reads (3%) | catalogued as COSV101458775; called by muse, mutect2
- SACS | c.9924C>T p.H3308= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV101207473; called by muse, mutect2, varscan2
- THBD | c.1329C>T p.D443= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV101001887; called by muse, mutect2, varscan2
- TMEM70 | c.472C>T p.L158= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV100384122; called by muse, mutect2, varscan2
- ZDHHC17 | c.39C>T p.D13= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs747649941, COSV100602131; called by muse, mutect2, varscan2
- FAS | c.*102T>C | 3'UTR (SNP) | VAF 14/62 reads (23%) | catalogued as CM033041, CM994522, COSV58240116; called by muse, mutect2, varscan2
- GLIPR1L2 | c.670+79dup | Intron (INS) | VAF 10/82 reads (12%) | called by mutect2, pindel, varscan2
- MAPK12 | c.314+302G>T | Intron (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99299386; called by muse, mutect2, varscan2
